Surgical pathology report (de-identified scan), TCGA case TCGA-XA-A8JR, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site  University of Minnesota, specimen TCGA-XA-A8JR-01A (Primary Tumor).

[page 1 of 7]
Normal Sample ID:

SPECIMEN(S):

A: Anterior bladder neck margin

B: Prostate left base

C: Left prostate apex

D: Right pelvic lymph nodes

E: Left pelvic lymph nodes

F: Prostate and seminal vesicles

FINAL DIAGNOSIS:

A. Bladder, anterior bladder neck, margin biopsy (including AFS):

- No evidence of malignancy.

B. Prostate, left base, margin biopsy(including BFS):

- No evidence of malignancy.

C. Prostate, left prostate apex, margin biopsy(including CFS):

- No evidence of malignancy.

D. Lymph node, right pelvic, lymph node dissection:

- No evidence of malignancy in three lymph nodes (0/3).

E. Lymph node, left pelvic, lymph node dissection:

- No evidence of malignancy in four lymph nodes (0/4).

F. Prostate and seminal vesicles, prostatectomy:

- Adenocarcinoma, acinar type.
- Gleason score 4 + 3, tertiary 5 (less than 5%).
- Involved in right anterior, right posterior, left anterior, and

ICD-O-3

Adenocarcinoma NOS 8440/3
Site: Prostate NOS C61.9

9/21/27/14

[page 2 of 7]
left posterior quadrant.

- 20% of tissue involved by carcinoma.
- Distal and proximal urethral margins involved by adenocarcinoma.
- No capsular invasion is seen.
- Perineural invasion is present.
- Lymphovascular space invasion present.

COMMENT:

Case Summary

Procedure: Radical prostatectomy

Prostate Size

Weight: 44 g

Size: 4.1 x 3.8 x 3.2 cm

Lymph Node Sampling: Pelvic lymph node dissection

Histologic Type: Adenocarcinoma (acinar, not otherwise specified)

Histologic Grade: (Note B)

Gleason Pattern

Primary Pattern: Grade 3

Secondary Pattern: Grade 4

Tertiary Pattern: Grade 5

Total Gleason Score: 7

Tumor Quantitation (Note C)

Proportion (percentage) of prostate involved by tumor: 20

Extraprostatic Extension: Not identified

Seminal Vesicle Invasion: Not identified

Margins: Margin(s) involved by invasive carcinoma (Bladder neck)

[page 3 of 7]
Treatment Effect on Carcinoma: Not applicable

Lymph-Vascular Invasion: Present

Perineural Invasion: Present

Pathologic Staging (pTNM): pT2c pN0

Primary Tumor (pT): pT2c: Bilateral disease

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined: 7

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: High-grade prostatic intraepithelial neoplasia (PIN), Nodular prostatic hyperplasia

CLINICAL HISTORY:

The patient is a -year-old man with prostate cancer. Operative

Procedure: Prostatectomy.

GROSS:

Six formalin-filled containers are received, each labeled with the patient's name and medical record number.

- A. The first container is labeled "A-anterior bladder neck margin." The specimen consists of a 0.3 x 0.2 x 0.1 cm tissue fragment. The specimen is previously frozen and entirely submitted in cassette A1.
- B. The second container is labeled "B-prostate biopsy, left base ."

[page 4 of 7]
The specimen consists of a 0.7 x 0.2 x 0.2 cm tissue fragment. The specimen is previously frozen and entirely submitted in cassette B1.

C. The third container is labeled "C-left prostate apex." The specimen consists of a 0.5 x 0.3 x 0.2 cm tissue fragment. The specimen is previously frozen and entirely submitted in cassette C1.

D. The fourth container is labeled "D-right pelvic lymph node." The specimen consists of a 5.3 x 3.0 x 1.7 cm fragment of fibroadipose tissue.

Summary of Sections:

D1 - one possible lymph node.

D2 - two possible lymph nodes.

D3 - one possible lymph node.

E. The fifth container is labeled "E-left pelvic lymph nodes." The specimen consists of three fibroadipose tissue fragment ranging in size from 4.5 x 1.5 x 0.5 cm to 3.0 x 1.0 x 0.5 cm.

Summary of Sections:

E1 - one possible lymph node.

E2 - one possible lymph node.

E3 - one possible lymph node.

F. The sixth container is labeled "F-prostate and seminal vesicles."

The specimen consists of a 44.1 gm prostate measuring 3.8 cm from anterior to posterior, 4.1 cm from left to right and 3.2 cm from inferior to superior. Attached to the prostate are a right seminal vesicle measuring 5.0 x 1.5 x 0.5 cm, a right vas deferens measuring 6.2 x 0.5 cm, a left seminal vesicle measuring 4.8 x 1.6 x 0.5 cm and a left

[page 5 of 7]
vas deferens measuring 5.5 x 0.5 cm. The anterior midline is inked blue. The surface is otherwise inked black. Serial sectioning reveals yellow-tan nodular cut surfaces without distinct lesions.

Representative tissue was procured for potential future studies from specimen F.

Summary of Sections:

F1 - LDUMA.

F2 - LDUMB.

F3 - LDUMC.

F4 - LDUMD.

F5 - LDUME.

F6 - RDUMA.

F7 - RDUMB.

F8 - RDUMC.

F9 - RDUMD.

F10 - RAA.

F11 - RPA.

F12 - LAA.

F13 - LPA.

F14 - RAB.

F15 - RPB.

F16 - LAB.

F17 - LPB.

F18 - RAC.

F19 - RPC.

[page 6 of 7]
F20 - LAC.

F21 - LPC.

F22 - RAD.

F23 - RPD.

F24 - LAD.

F25 - LPD.

F26 - RAE.

F27 - RPD.

F28 - LAE.

F29 - LPE.

F30 - RAF.

F31 - RPD.

F32 - LAF.

F33 - LPF.

F34 - Proximal urethral margin en face.

F35 - Representative cross sections of right seminal vesicle and vas deferens.

F36 - Representative cross sections of left seminal vesicle and vas deferens.

F37-F38 - Unattached adipose tissue also in container.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

AFS1: Bladder neck, anterior margin, biopsy. "Negative for malignancy."

BFS1: Prostate, left base, biopsy. "Negative for malignancy."

[page 7 of 7]
CFS1: Prostate, left apex, biopsy. "Negative for malignancy."

MICROSCOPIC:

Microscopic examination is performed. Permanent sections confirm the frozen section diagnosis.

H.PAA Discrepancy		☒

Source: NCI Genomic Data Commons file b63f1abb-fafc-4e45-9965-211b48612302 (TCGA-XA-A8JR.587379B6-9AF9-471D-834C-668555ABC32A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).